Gene-level copy-number profile of tumor specimen TCGA-WE-A8ZX-06A from TCGA case TCGA-WE-A8ZX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.9 years (16,762 days).
Specimen TCGA-WE-A8ZX-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c5776d9c-3101-4d43-88ff-e671977ee150.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-A8ZX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d8d0991-bc6d-49e2-a298-a8b11fb53bac

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 2: 23,750; copy number 3: 7,112; copy number 4: 21,777; copy number 5: 2,264; copy number 6: 4,642; copy number 8: 60; copy number 9: 94; copy number 10: 11; copy number 11: 1; copy number 12: 24; copy number 14: 5; copy number 18: 37; copy number 19: 14; copy number 65: 11; copy number 71: 1; copy number 79: 3; copy number 93: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-A8ZX-06A-11D-A371-01): tumor purity 0.62, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:116,819,220–116,830,370, 1 gene: AC010267.1.
- chr9:21,966,929–22,214,672, 9 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 205 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,471,452–69,968,336, 6 genes, copy number 11–93: RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P.
- chr3:70,125,070–70,140,488, 2 genes, copy number 93: AC139700.1, UQCRHP4.
- chr3:71,785,428–71,827,471, 2 genes, copy number 79: AC096970.1, RN7SL271P.
- chr3:72,006,774–72,006,975, 1 gene, copy number 79: UBE2Q2P9.
- chr3:72,202,944–72,740,525, 9 genes, copy number 10: AC112219.1, AC134508.2, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4.
- chr3:72,772,539–72,773,471, 1 gene, copy number 10: AC134050.1.
- chr3:107,104,911–107,107,000, 1 gene, copy number 10: AC074043.1.
- chr3:107,834,586–108,589,644, 11 genes, copy number 12–14 (within-gene range 2–14): LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A.
- chr3:108,907,792–109,410,084, 15 genes, copy number 12: GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12.
- chr3:109,471,329–109,471,812, 1 gene, copy number 12: PPIAP15.
- chr12:40,068,243–41,574,745, 14 genes, copy number 9 (within-gene range 4–9): RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1.
- chr12:43,353,866–47,369,935, 62 genes, copy number 18–65 (broad region; genes not listed).
- chr12:48,627,879–49,188,484, 39 genes, copy number 9 (within-gene range 5–9): OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B, CCNT1, TEX49, AC117498.1, ADCY6, MIR4701, ADCY6-DT, AC117498.2, Y_RNA, CACNB3, DDX23, RND1, RNU6-600P, AC073610.1, AC073610.2, CCDC65, FKBP11, ARF3, WNT10B, RNU6-940P, WNT1, DDN, AC011603.3, DDN-AS1, PRKAG1, KMT2D, RHEBL1, AC011603.4, DHH, AC011603.1, LMBR1L, TUBA1B, AC011603.2, Y_RNA.
- chr12:49,536,677–50,289,231, 41 genes, copy number 9: AC020612.4, KCNH3, MCRS1, PRPF40B, AC020612.3, FAM186B, RNU6-834P, POLR2KP1, AC020612.1, HIGD1AP9, FMNL3, TMBIM6, AC020612.2, LSM6P2, NCKAP5L, BCDIN3D-AS1, BCDIN3D, AC131157.1, RPL35AP28, FAIM2, LINC02395, LINC02396, AQP2, AC025154.2, AC025154.1, AQP5, AQP6, RACGAP1, ASIC1, SMARCD1, GPD1, COX14, AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
